Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A3XE, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A3XE-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 1.5 x 0.4 x 1.8 cm

Tumor features: Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Breslow's depth is 3 mm.

ICD-O-3
melanoma, NOS
8720/3

Site:
C44F-skin, NOS
C44.9

path: skin, trunk
C44.5

5-17-12
RD

Source: NCI Genomic Data Commons file 617f1d3a-5802-4fa2-af09-fc47ede9c5f2 (TCGA-EB-A3XE.0495197B-B5CD-484A-8531-34ADE693294B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).